Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3X2, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3X2-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender:

Ref. Physician: .

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

History of muscle invasive

1CD-0-3

Carcinoma, urothelial, NOS

8/20/13

Specimens Submitted:

1: Right ureter (fs)

2: Left ureter (fs)

3: Left pelvic lymph nodes (fs)

4: Right common iliac lymph nodes

5: Right pelvic lymph nodes

6: Pre-sacral lymph node

7: Left common iliac lymph nodes

8: Bladder, prostate and seminal vesicles

9: Right vas deferens

10: Left vas deferens

Site: path: bladder NOS C67.9

CCF: bladder wall, lateral

C67.2

5-23-12 eo

DIAGNOSIS:

1. Right ureter, biopsy:

- Benign segment of ureter

2. Left ureter, biopsy:

- Benign segment of ureter

3. Left pelvic lymph nodes (fs):

Part # 3

Lymph Node Dissection:

Metastatic urothelial cell carcinoma

Number of lymph nodes examined: 7

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 2cm.

Size of the largest metastatic focus : 2 cm.

Extranodal extension is identified

4. Right common iliac lymph nodes:

Part # 4

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 4

5. Right pelvic lymph nodes:

Part # 5

Lymph Node Dissection:

Benign lymph nodes

Metastatic urothelial carcinoma

Number of lymph nodes examined: 5

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 1.1cm.
Size of the largest metastatic focus : 0.1 cm.
Extranodal extension is not identified

6. Pre-sacral lymph node:

Part # 6

Lymph Node Dissection:

Benign fibroadipose tissue

7. Left common iliac lymph nodes:

Part # 7

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

8. Bladder, prostate and seminal vesicles:

Part # 8

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Not identified

Bladder Local Invasion:

Perivesical soft tissues

Invasion is extensive

Extravesical Tumor Extension:

Periurethral stroma in the proximal prostate

Vascular Invasion:

Identified

Extensive

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Tumor approaches to 1 mm of the inked soft tissue margin

Non-Neoplastic Mucosa:

Unremarkable

Prostate:

Nodular hyperplasia

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Metastatic carcinoma present in 2 of 4 nodes

The Pathologic Stage is (AJCC

pT3 (Invasion of perivesicle soft tissue)

PR0 (No involvement of prostate)

Comment: In the 7th edition of AJCC this tumor would be staged as pT3bN2. The tumor cells lack immunoreactivity for chromogranin and synaptophysin. E-cadherin shows diffuse membranous stain.

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

9. Right vas deferens, biopsy:

- Benign vas deferens

10. Left vas deferens, biopsy:

- Benign vascular and soft tissue

10-10-2014 10:00 AM

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	B-CATENIN	
	CHR	
	SYN	
	NEG CONT	
	IMM RECUT	
	E-CADHERIN	

Gross Description:

1) Received fresh labeled "right ureter" is a 0.7 x 0.5 x 0.3 cm yellow tan soft tissue fragment. It is entirely submitted in one cassette.

Summary of sections:

FSC - frozen section control

2). Received fresh labeled "left ureter" is a 0.5 x 0.4 x 0.4 cm yellow tan soft tissue fragment. It is entirely submitted in one cassette.

Summary of sections:

FSC - frozen section control

3) The specimen is received fresh for frozen section consultation labeled "Left pelvic lymph nodes." It consists of a segment of yellow-tan adipose tissue measuring 6 x 2 x 1.5 cm. On cut section, there are multiple lymph nodes identified measuring up to 2 x 1.8 cm in greatest dimensions. On cut section of the largest lymph node, it shows infiltration by gritty white-tan tumor. Representative section is submitted for frozen section consultation. Representative section of the positive lymph node is submitted to TPS. Remaining lymph nodes are entirely submitted.

Summary of sections:

FSC – frozen section control

PN- additional sections of positive node

LN-lymph nodes

4). The specimen is received fresh, labeled "Right common iliac lymph nodes" and consists of a single lymph node measuring 3.5 x 1.5 x 0.7cm. The lymph node is bisected and entirely submitted.

Summary of sections:

LN - lymph node

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

5) The specimen is received fresh, labeled "Right pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 x 0.2 cm up to 6 x 1 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes
LLN-largest lymph node

6) The specimen is received fresh, labeled "Presacral lymph node" and consists of two fatty yellow-tan lymph nodes measuring 1.8 x 1.7 cm in greatest dimensions. All identified lymph nodes are submitted.

Summary of sections:

LLN - largest lymph node
BLN - bisected lymph nodes

7) The specimen is received fresh, labeled "Left common iliac lymph nodes" and consists of a single lymph node measuring 0.8 x 0.7 x 0.3 cm. The lymph node is entirely submitted.

Summary of sections:

LN - lymph node

8) The specimen is received fresh, labeled "Bladder, prostate and seminal vesicles". It consists of a bladder, prostate and seminal vesicles measuring 8.7 cm from superior to inferior, 10 cm laterally and 8.5 cm from anterior to posterior. The bladder measures 8.5 x 8 x 6 cm, the prostate measures 5 x 5 x 4.5 cm, the right seminal vesicle measures 2 x 1 x 0.7 cm, the right vas deferens measures 1.2 cm in length and 0.3 cm in diameter, the left seminal vesicle measures 2.1 x 1.1 x 0.6 cm, and the left vas deferens measures 1 cm in length and 0.3 cm in diameter. The anterior aspect of the bladder is inked blue and the posterior black. The right lobe of the prostate is inked green, the left lobe of prostate is inked blue. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal ill defined papillary/polypoid mass measuring 7 x 6 cm which is grossly involves the entire left side of the bladder and encasing the left ureteral orifice and 2.2 cm from the right ureteral orifice. Both ureters are probe patent. The right ureter measures to 0.3 cm in maximum diameter. The left ureter is dilated and measures up to 1.5 cm in circumference. The lesion is sectioned to reveal full thickness involvement of the bladder wall (2.8 cm). The extension to the inked fat is grossly identified. The remaining bladder mucosa has an irregular appearance with scattered 0.2 to 0.3 cm in diameter polyps throughout the entire bladder mucosal surface. Four perivesical lymph nodes are grossly identified. The prostate is serially sectioned to reveal nodular appearance. Representative sections are submitted. The specimen is photographed. is submitted. Gross photos were taken.

Summary of sections:

UTHM - urethral margin
RUM - right ureter margin
LUM - left ureter margin
RUO - right ureter orifice
LUO - left ureter orifice
TRI - trigone
RP - right posterior wall
RA - right anterior wall
DOM - dome
LP - left posterior wall
LA - left anterior wall
F - perivesical fat
RSV - right seminal vesicle
LSV - left seminal vesicle
RAP - right apex prostate
LAP - left apex prostate
RAM - right anterior mid prostate
RPM - right posterior mid prostate
LAM - left anterior mid prostate
LPM - left posterior mid prostate
RAB - right anterior base prostate
RPB - right posterior base prostate
LAB - left anterior base prostate
LPB - left posterior base prostate
BLN-bisected lymph node

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

LN--lymph node

9) The specimen is received in formalin labeled "Right vas deferens" and consists of a 4.2 x 0.5 x 0.3 cm cylindrical fibrotic soft tissue. The specimen is sectioned to reveal a homogeneous tan-white cut surface. Representative sections are submitted.

Summary of sections:
U-undesignated

10) The specimen is received in formalin labeled "Left vas deferens" and consists of a 4.2 x 0.5 x 0.3 cm cylindrical fibrotic soft tissue. The soft tissue is dissected to reveal a homogeneous tan-white cut surface. Representative sections are submitted.

Summary of sections:
U-undesignated

Summary of Sections:

Part 1: Right ureter (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Left ureter (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: Left pelvic lymph nodes (fs)

Block	Sect. Site	PCs
1	fsc	1
2	ln	2
1	pn	1

Part 4: Right common iliac lymph nodes

Block	Sect. Site	PCs
2	LN	2

Part 5: Right pelvic lymph nodes

Block	Sect. Site	PCs
2	bln	2
2	lln	2
1	ln	1

Part 6: Pre-sacral lymph node

Block	Sect. Site	PCs
1	BLN	1
4	LLN	4

Part 7: Left common iliac lymph nodes

Block	Sect. Site	PCs
1	ln	1

Part 8: Bladder, prostate and seminal vesicles

Block	Sect. Site	PCs
1	BLN	2

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

2	DOM	3
2	F	3
4	LA	6
2	LAB	3
1	LAM	2
1	LAP	2
1	LN	2
4	LP	5
2	LPB	3
2	LPM	3
1	LSV	3
1	LUM	2
2	LUO	2
2	RA	3
1	RAB	3
1	RAM	2
1	RAP	2
2	RP	3
1	RPB	3
1	RPM	2
1	RSV	2
1	RUM	2
1	RUO	3
2	TRI	3
1	UTHM	3

Part 9: Right vas deferens

Block	Sect. Site	PCs
1	U	1

Part 10: Left vas deferens

Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Right ureter (fs): Benign
Permanent Diagnosis: same
2. Frozen Section Diagnosis: Left ureter (fs): Benign
Permanent Diagnosis: same
3. Frozen Section Diagnosis: Left pelvic lymph nodes (fs): Metastatic carcinoma
Permanent Diagnosis: same

Source: NCI Genomic Data Commons file 64703b2f-15f6-4377-9e97-a2242e46eddb (TCGA-DK-A3X2.8360D3E9-526D-4E99-86E0-C33F785DCF15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).